Somatic mutation profile of tumor specimen MMRF_2353_1_BM_CD138pos (aliquot MMRF_2353_1_BM_CD138pos_T2_KHS5U_K14037) from MMRF case MMRF_2353, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.0 years (20,807 days).
Specimen MMRF_2353_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1aa996a-0b9f-42d8-86f3-9696f9b67621.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2353_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2353_1_PB_Whole_C1_KHS5U_K14036; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dabf8ae4-7cc1-4b70-bbc5-47c2253034e7

The open-access MAF lists 82 somatic variants for this specimen: 30 protein-altering or splice-affecting, 13 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, 3'UTR 19, Silent 13, Intron 10, 3'Flank 3, 5'UTR 3, Nonsense Mutation 2, RNA 2, Frame Shift Del 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADA2 | c.1468A>G p.K490E (on ENST00000262607; = p.K249E on NM_177405.3) | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV52830949; called by muse, mutect2, varscan2
- ADGRV1 | c.10475C>A p.S3492Y | Missense Mutation (SNP) | VAF 27/279 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV67983969; called by muse, mutect2
- BEND3 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs781968033; called by muse, mutect2, varscan2
- CHD1 | c.776G>T p.C259F | Missense Mutation (SNP) | VAF 86/330 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as rs767417214; called by muse, mutect2, varscan2
- FAM170A | c.782A>G p.H261R | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs199949750; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 53/104 reads (51%) | catalogued as rs760757380; called by mutect2, varscan2
- IGHV2-70 | c.289A>C p.N97H | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs368209907; called by muse, varscan2
- KRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55534434, COSV55579983, COSV55703886; called by muse, mutect2, varscan2
- PER3 | c.3340C>T p.R1114C | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs750738867; called by muse, mutect2, varscan2
- RUNX1T1 | c.1062G>A p.W354* (on ENST00000265814 / NM_001198628.1; = p.W327* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 76/203 reads (37%) | catalogued as COSV56137625; called by muse, mutect2, varscan2
- RYR2 | c.12292G>A p.V4098I | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.115); catalogued as rs1047248475, COSV63661279, COSV63692480; called by muse, mutect2, varscan2
- TRPM3 | c.4798G>A p.D1600N (on ENST00000357533 / NM_001366142.2; = p.D1455N on NM_020952.6) | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.984); catalogued as rs1564189547; called by muse, mutect2, varscan2
- ACLY | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- AKAP6 | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APOBR | c.1458G>T p.Q486H (on ENST00000431282; = p.Q495H on NM_018690.4) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- ASXL3 | c.3242G>T p.S1081I | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BCL11B | c.1492C>T p.P498S (on ENST00000357195 / NM_001282237.2; = p.P427S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- BNC2 | c.1817del p.P606Rfs*7 | Frame Shift Del (DEL) | VAF 21/150 reads (14%) | called by mutect2, pindel, varscan2
- BPIFC | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- CES5A | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAJC13 | c.64G>C p.G22R | Missense Mutation (SNP) | VAF 144/499 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF4A3 | c.1213A>G p.M405V | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV1-69D | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, varscan2
- IP6K2 | c.338G>A p.W113* | Nonsense Mutation (SNP) | VAF 164/597 reads (27%) | called by muse, mutect2, varscan2
- KCTD8 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYB | c.918G>T p.E306D | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP2R5E | c.764C>A p.P255H | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPL10L | c.23G>T p.C8F | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- TMEM143 | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB21 | c.2814T>G p.I938M | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSPG5 | c.1431C>T p.S477= | Silent (SNP) | VAF 43/122 reads (35%) | called by muse, mutect2, varscan2
- EML6 | c.5136G>C p.R1712= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as rs1387606159; called by muse, mutect2, varscan2
- FSTL5 | c.1089T>C p.H363= | Silent (SNP) | VAF 62/132 reads (47%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.339T>C p.Y113= | Silent (SNP) | VAF 40/95 reads (42%) | called by muse, varscan2
- IGKV1-33 | c.132T>G p.T44= | Silent (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2
- MTUS2 | c.492A>G p.A164= | Silent (SNP) | VAF 56/137 reads (41%) | catalogued as rs144865341; called by muse, mutect2, varscan2
- MYOM2 | c.1659C>T p.S553= | Silent (SNP) | VAF 79/115 reads (69%) | catalogued as rs775972053; called by muse, mutect2, varscan2
- OGFOD3 | c.636C>A p.S212= | Silent (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.996A>G p.K332= | Silent (SNP) | VAF 105/321 reads (33%) | called by muse, mutect2, varscan2
- RBMXL3 | c.2700C>T p.S900= | Silent (SNP) | VAF 97/100 reads (97%) | called by muse, mutect2, varscan2
- SETD2 | c.567T>G p.S189= | Silent (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- STOML1 | c.690A>G p.P230= | Silent (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- VWA1 | c.939G>A p.P313= | Silent (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2
- ADAMTSL1 | c.1341+345C>T | Intron (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- ADIPOQ | c.*3367G>T | 3'UTR (SNP) | VAF 16/24 reads (67%) | called by muse, varscan2
- ARNTL2 | chr12:27421221 G>T | 3'Flank (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2, varscan2
- ATP6V0A2 | c.196+118C>G | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, varscan2
- C1QTNF2 | c.*1233del | 3'UTR (DEL) | VAF 17/31 reads (55%) | catalogued as rs1238908430; called by mutect2, pindel, varscan2
- C7orf26 | c.1149-244del | Intron (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel, varscan2
- CNOT2 | c.*37T>C | 3'UTR (SNP) | VAF 92/202 reads (46%) | called by muse, varscan2
- CYP11B2 | c.*92C>T | 3'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- DOCK10 | c.*514A>C | 3'UTR (SNP) | VAF 45/90 reads (50%) | called by muse, mutect2, varscan2
- ERMP1 | c.*755T>G | 3'UTR (SNP) | VAF 29/100 reads (29%) | called by muse, mutect2, varscan2
- ETV1 | chr7:13891382 A>C | 3'Flank (SNP) | VAF 59/219 reads (27%) | called by muse, mutect2, varscan2
- GPR161 | c.-139+911G>A | Intron (SNP) | VAF 44/98 reads (45%) | catalogued as rs1201030784; called by muse, mutect2, varscan2
- IGF1R | c.*2858_*2859del | 3'UTR (DEL) | VAF 4/85 reads (5%) | catalogued as rs1491390352; called by pindel, varscan2
- INPP4B | chr4:142025524 C>T | 3'Flank (SNP) | VAF 52/122 reads (43%) | called by muse, mutect2, varscan2
- LCP2 | c.*70C>T | 3'UTR (SNP) | VAF 18/525 reads (3%) | called by muse, mutect2
- LRRC15 | c.*2362G>A | 3'UTR (SNP) | VAF 45/160 reads (28%) | catalogued as rs781155356; called by muse, mutect2, varscan2
- LTB | c.162+96G>A | Intron (SNP) | VAF 26/51 reads (51%) | catalogued as rs568160727, COSV53000207, COSV53001296; called by muse, mutect2, varscan2
- LTBP4 | c.1886-20C>A | Intron (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2
- LYPD4 | c.*59A>C | 3'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- MAD2L2 | c.232-289T>G | Intron (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- MCTP2 | c.969+1683T>C | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as rs547271614; called by muse, mutect2, varscan2
- MDGA1 | c.-1021C>T | 5'UTR (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- MED28 | c.*1931A>G | 3'UTR (SNP) | VAF 282/608 reads (46%) | catalogued as rs566135470; called by muse, mutect2, varscan2
- MIR5195 | n.12A>T | RNA (SNP) | VAF 53/133 reads (40%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851123 T>A | 5'Flank (SNP) | VAF 107/266 reads (40%) | catalogued as rs562053532; called by muse, mutect2, varscan2
- MROH5 | c.3779-98del | Intron (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- MSR1 | c.*467T>C | 3'UTR (SNP) | VAF 28/41 reads (68%) | called by muse, mutect2, varscan2
- NGFR | c.*1045_*1046del | 3'UTR (DEL) | VAF 68/178 reads (38%) | called by pindel, varscan2
- NR1H3 | c.-38+98G>T | Intron (SNP) | VAF 47/90 reads (52%) | called by muse, mutect2, varscan2
- PTAR1 | c.*6134A>G | 3'UTR (SNP) | VAF 113/168 reads (67%) | called by muse, mutect2, varscan2
- RRP15 | c.*1671T>C | 3'UTR (SNP) | VAF 70/133 reads (53%) | called by muse, mutect2, varscan2
- RRP15 | c.*1777dup | 3'UTR (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- SCN8A | c.*611T>C | 3'UTR (SNP) | VAF 44/101 reads (44%) | called by muse, mutect2, varscan2
- SEC24A | c.-198G>A | 5'UTR (SNP) | VAF 81/166 reads (49%) | called by muse, mutect2, varscan2
- SLC66A1L | n.198C>T | RNA (SNP) | VAF 167/637 reads (26%) | catalogued as rs776841282; called by muse, mutect2, varscan2
- SNRK | c.*2041del | 3'UTR (DEL) | VAF 18/58 reads (31%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.-43G>T | 5'UTR (SNP) | VAF 23/578 reads (4%) | called by muse, mutect2
- ZNF561 | c.*651C>T | 3'UTR (SNP) | VAF 42/147 reads (29%) | catalogued as rs1023609590; called by muse, mutect2, varscan2
- ZNFX1 | chr20:49280689 G>A | 5'Flank (SNP) | VAF 62/115 reads (54%) | called by muse, mutect2, varscan2
